CGCI case BLGSP-71-30-00659 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ea6a7522-728b-407e-94db-3939e1be9869

Demographics
Sex at birth: male; Age at index: 71 years; Vital status: Dead; Days to death: 224 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 71.9 years (26,265 days); Year of diagnosis: 2013; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 213 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Axillary lymph nodes; Sites of involvement: Adrenal gland, NOS / Pancreas, NOS / Mesentery / Soft tissue.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: No; Lymph node involved site: Axillary; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 15.5 cm.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX; Days to treatment start: 27 days; Days to treatment end: 102 days; Number of cycles: 4; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-IVAC; Days to treatment start: 27 days; Days to treatment end: 102 days; Number of cycles: 4; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 27 days; Days to treatment end: 102 days; Number of cycles: 4; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 127 days; Days to treatment end: 154 days; Treatment dose: 35; Treatment outcome: Progressive Disease; Treatment anatomic sites: Lymph Node(s) Axilla.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 161 days; Days to treatment end: 174 days; Treatment dose: 30; Treatment outcome: Progressive Disease; Treatment anatomic sites: Other.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 198 days; Days to treatment end: 204 days; Treatment dose: 20; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Pharmaceutical Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 126 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of trunk, NOS; Days to recurrence: 126 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 213 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (FISH): Normal.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- FOXP1 (IHC): Positive.
- IRF4 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- LMO2 (IHC): Negative.
- MYC translocation (FISH): Abnormal, NOS.
- Test (IHC): Negative; Specialized molecular test: GCET1.
- Lactate Dehydrogenase 438 [Blood test normal range upper: 240].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Weight: 68.5 kg; Height: 173 cm; BMI: 22.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00659-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00659-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Biospecimen anatomic site: Lymph Node.
- Sample BLGSP-71-30-00659-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00659-01-BCL2: Tissue microarray coordinates: C5,D5.
  Slide BLGSP-71-30-00659-01-EBER: Tissue microarray coordinates: C5,D5.
  Slide BLGSP-71-30-00659-01-Ki67: Tissue microarray coordinates: C5,D5.
  Slide BLGSP-71-30-00659-01-CD20: Tissue microarray coordinates: C5,D5.
  Slide BLGSP-71-30-00659-01-CD10: Tissue microarray coordinates: C5,D5.
  Slide BLGSP-71-30-00659-01-CD3: Tissue microarray coordinates: C5,D5.
  Slide BLGSP-71-30-00659-01-BCL6: Tissue microarray coordinates: C5,D5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 3; Extranodal involvment other: soft tissue invading mesentery; Lymph nodes examined: Yes.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 438; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: FOXP1.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: MUM1.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: GCET1.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: LMO2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: Right flank subcutaneous mass; New tumor event diagnosis evidence: Convincing Imaging; New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CODOXR/IVACR (Magrath protocol, M omitted, IVACR 50% reduction 2nd cycle); Pharma adjuvant cycles count: 4; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 35; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2, Extranodal radiation field list: Extranodal radiation field: Lymph node, locoregional (specify site).
- Treatments, Treatment 3: Therapy regimen: Progression after initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 30; Targeted nodal region other: right flank; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 4: Therapy regimen: Progression after initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 20; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 4, Extranodal radiation field list: Extranodal radiation field: Chest Wall; Extranodal radiation field: Eye.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00659-01A-01E-0001-01:
- % tumour: 95
